Gene-level copy-number profile of tumor specimen TCGA-DX-A6YZ-01A from TCGA case TCGA-DX-A6YZ, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Fibromyxosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Age at diagnosis: 59.9 years (21,886 days).
Specimen TCGA-DX-A6YZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.686e8989-223c-4fb4-9e48-8d5dc94b9e60.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A6YZ-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/02a7c790-80c3-4b3a-b027-8479d6d89d8b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 114; copy number 1: 1,714; copy number 2: 13,933; copy number 3: 15,195; copy number 4: 22,066; copy number 5: 2,514; copy number 6: 2,638; copy number 7: 681; copy number 8: 157; copy number 9: 65; copy number 10: 147; copy number 11: 5; copy number 12: 46; copy number 13: 10; copy number 14: 3; copy number 15: 22; copy number 17: 323; copy number 18: 3; copy number 20: 4; copy number 23: 20; copy number 25: 6; copy number 26: 10; copy number 33: 54; copy number 37: 23; copy number 38: 40; copy number 63: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A6YZ-01A-12D-A350-01): tumor purity 0.5, ploidy 3.33, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 114 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,106,543–29,826,711, 114 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 797 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:61,240,898–62,286,225, 5 genes, copy number 11: AL356131.1, MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1.
- chr6:66,710,242–66,728,904, 2 genes, copy number 12: AL450336.1, RNU7-66P.
- chr6:67,878,316–68,635,161, 11 genes, copy number 9–15: AL713998.1, AL713998.3, AL713998.4, AL713998.2, AL646090.2, AL646090.1, AL593844.1, LINC02549, AL606923.2, AL606923.1, AL391807.1.
- chr8:37,858,618–40,016,391, 62 genes, copy number 9 (broad region; genes not listed).
- chr10:42,185,339–42,552,822, 9 genes, copy number 12 (within-gene range 8–12): IGKV1OR10-1, AL031601.1, AL031601.2, PABPC1P8, BX322639.1, CCNYL2, AL391099.1, LINC00839, ZNF37BP.
- chr12:68,610,855–68,671,901, 1 gene, copy number 38 (within-gene range 3–38): RAP1B.
- chr12:68,642,519–73,143,858, 78 genes, copy number 37–63 (broad region; genes not listed).
- chr12:76,115,711–76,139,671, 3 genes, copy number 14: AC233290.2, AC233290.1, RNU6-1271P.
- chr12:76,763,588–78,540,675, 16 genes, copy number 15–26 (within-gene range 7–26): ZDHHC17, CSRP2, AC124784.1, AC025161.1, E2F7, AC079030.1, LINC02464, NAV3, AC073591.1, AC138331.1, AC073571.1, PRXL2AP1, LINC02424, AC128707.1, AC130415.1, AC079362.1.
- chr12:79,341,205–79,503,396, 1 gene, copy number 25 (within-gene range 8–25): AC027288.3.
- chr12:79,500,119–80,937,925, 26 genes, copy number 10–25: AC027288.2, AC027288.1, NOP56P3, PAWR, AC073569.2, PPP1R12A, AC073569.3, AC073569.1, RNA5SP363, PPP1R12A-AS1, SNRPGP20, RPL7P38, RNU7-106P, OTOGL, AC078817.1, RN7SKP261, PTPRQ, AKIRIN1P1, AC074031.1, MYF6, MYF5, LINC01490, LIN7A, MIR617, AC078886.1, MIR618.
- chr15:44,537,125–48,645,721, 96 genes, copy number 10 (within-gene range 2–10) (broad region; genes not listed).
- chr15:48,712,928–50,182,817, 29 genes, copy number 12–23: CEP152, AC084757.1, AC084757.2, AC012379.1, AC012379.2, SHC4, EID1, AC091073.1, KRT8P24, SECISBP2L, Y_RNA, RN7SL577P, AC013452.2, COPS2, Y_RNA, GALK2, NDUFAF4P1, MIR4716, AC013452.1, RN7SL307P, FAM227B, AC022306.3, AC022306.1, FGF7, DTWD1, AC025040.2, ATP8B4, AC025040.1, RNA5SP394.
- chr15:50,417,385–50,514,421, 4 genes, copy number 20 (within-gene range 2–20): AHCYP7, USP8, RNA5SP395, AC012170.1.
- chr15:52,109,263–52,295,804, 8 genes, copy number 15: BCL2L10, GNB5, AC023906.3, AC023906.4, Y_RNA, CERNA1, MYO5C, MIR1266.
- chr15:53,910,769–53,984,010, 2 genes, copy number 18: AC084759.3, AC084759.2.
- chr15:54,048,588–54,050,876, 1 gene, copy number 18: AC010867.1.
- chr15:62,823,957–64,163,022, 30 genes, copy number 10: MIR190A, AC103740.1, AC103740.2, AC079328.1, TPM1, TPM1-AS, AC079328.2, AC087612.1, LACTB, RPS27L, RAB8B, APH1B, CA12, LINC02568, AC007950.1, AC007950.2, USP3, USP3-AS1, FBXL22, HERC1, AC073167.1, MIR422A, AC015914.2, DAPK2, AC015914.1, CIAO2A, SNX1, Y_RNA, SNX22, PPIB.
- chr15:67,063,763–69,843,120, 53 genes, copy number 17 (within-gene range 4–17): SMAD3, AC012568.1, AAGAB, RPS24P16, IQCH, IQCH-AS1, C15orf61, AC016355.1, MAP2K5, HNRNPA1P5, SKOR1, AC009292.2, AC009292.1, RNU6-1, AC022254.1, AC135628.1, PIAS1, AC107871.1, CALML4, CLN6, HMGN2P40, AC107871.2, FEM1B, ITGA11, AC100825.1, CORO2B, CARS1P1, ANP32A, MIR4312, SPESP1, AC087639.1, AC087639.2, AC027088.1, NOX5, AC027088.5, AC027088.4, AC027088.3, EWSAT1, AC027088.2, GLCE, AC026992.2, AC026992.1, PAQR5, AC027237.4, AC027237.3, Y_RNA, KIF23, AC027237.1, RPLP1, U3, AC027237.2, DRAIC, AC100826.1.
- chr15:76,993,359–77,485,607, 10 genes, copy number 13 (within-gene range 4–13): PSTPIP1, TSPAN3, AC090181.1, AC090181.3, AC090181.2, PEAK1, AC087465.1, AC060773.1, HMG20A, AC090984.1.
- chr17:15,829,369–22,706,703, 350 genes, copy number 12–33 (within-gene range 2–33) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 754. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
